Gene-level copy-number profile of tumor specimen C3N-01339-01 (profiled together with C3N-01339-02) from CPTAC case C3N-01339, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 68.6 years (25,041 days).
Specimen C3N-01339-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4e8def8b-e03b-410d-be3c-004a5a49fd3c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01339-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,261 have no estimate.
https://portal.gdc.cancer.gov/files/713d81f0-8a2c-48fc-b308-1961401de416

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 27,873; copy number 2: 26,609; copy number 3: 2,598; copy number 4: 1,085; copy number 5: 103; copy number 6: 10; copy number 7: 1; copy number 10: 3; copy number 11: 12; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr1:30,931,506–31,108,623, 5 genes: PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1.
- chr2:140,898,423–141,208,376, 4 genes (within-gene range 0–2): LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:75,384,059–75,580,199, 10 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15.
- chr4:186,104,419–186,555,567, 14 genes: FAM149A, AC104070.1, RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:109,528,119–109,529,008, 1 gene: PHB2P1.
- chr18:50,795,120–51,845,628, 17 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3.
- chr21:9,068,361–9,129,752, 3 genes: TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 130 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:26,711,551–26,749,997, 2 genes, copy number 5: AC113347.4, CCNB3P1.
- chr5:45,890,216–45,895,970, 1 gene, copy number 5: AC122694.1.
- chr7:66,376,044–66,506,223, 10 genes, copy number 6 (within-gene range 3–6): LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1.
- chr12:24,949,163–25,386,241, 13 genes, copy number 11–19 (within-gene range 3–19): AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1.
- chr15:24,954,986–26,134,001, 104 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 26,016. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
